Surgical pathology report (de-identified scan), TCGA case TCGA-61-2611, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2611-02A (Recurrent Tumor).

FINAL DIAGNOSIS:

PART 1: JEJUNUM, SEGMENTAL EXCISION -

- A. METASTATIC HIGH GRADE CARCINOMA, MORPHOLOGICALLY CONSISTENT WITH HIGH GRADE SEROUS PAPILLARY CARCINOMA, CHARACTERIZED BY -
1. MULTIPLE MASSES AND ADHESIONS, INVOLVING SEROSA, SUBSEROSAL ADIPOSE TISSUE AND FOCALLY INVADING MUSCULARIS PROPRIA OF THE SMALL BOWEL.
2. LARGEST MASS (3.0 X 2.0 X 1.0 CM) FORMS A SMALL BOWEL STRICTURE. TWO ADDITIONAL FOCAL STRICTURES SECONDARY TO SEROSAL TUMOR ARE IDENTIFIED.
3. SURGICAL MARGINS ARE POSITIVE FOR METASTATIC SEROUS CARCINOMA INVOLVING SEROSA AND SUBSEROSAL ADIPOSE TISSUE.
- B. SMALL BOWEL MUCOSA, NO SPECIFIC ABNORMALITIES.
- C. MULTIPLE REGIONAL LYMPH NODES ARE POSITIVE FOR METASTATIC CARCINOMA (3/13).

PART 2: SOFT TISSUE, UPPER ABDOMEN, LESION, BIOPSY -

METASTATIC HIGH GRADE SEROUS PAPILLARY CARCINOMA, INVOLVING FIBROADIPOSE SOFT TISSUE.

PART 3: SOFT TISSUE, GREATER CURVATURE OF STOMACH, BIOPSY -

METASTATIC HIGH GRADE SEROUS PAPILLARY CARCINOMA, INVOLVING FIBROADIPOSE SOFT TISSUE.

** Report Electronically Signed Out **
By Pathologist:

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

1CD-0-3

serous papillary cystadenocarcinoma 8460/6

Site: small bowel, NOS C 71.9

hw
2/17/15

Source: NCI Genomic Data Commons file dab76709-ec68-4748-89ff-6c32bc09dfa3 (TCGA-61-2611.29965B48-14CA-467F-B825-8BC99A99544B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).